Somatic mutation profile of tumor specimen TCGA-UY-A8OD-01A (aliquot TCGA-UY-A8OD-01A-11D-A364-08) from TCGA case TCGA-UY-A8OD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 67.3 years (24,588 days).
Specimen TCGA-UY-A8OD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9fb9dcc5-598e-4803-a589-b111467e24ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UY-A8OD-10A (Blood Derived Normal), aliquot TCGA-UY-A8OD-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d815778a-5db1-4850-b598-a2128b359c37

The open-access MAF lists 101 somatic variants for this specimen: 70 protein-altering or splice-affecting, 28 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 28, Nonsense Mutation 7, Frame Shift Del 6, RNA 2, Intron 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.2341C>T p.Q781* | Nonsense Mutation (SNP) | VAF 23/41 reads (56%) | catalogued as rs1555075781, COSV99586642; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.1303T>C p.W435R | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV53980952; called by muse, mutect2, varscan2
- ACTN1 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 22/63 reads (35%) | catalogued as COSV99516976; called by muse, mutect2, varscan2
- ADAMTS3 | c.566A>T p.Q189L | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV54398324; called by muse, mutect2, varscan2
- ADGRL1 | c.989C>G p.S330C (on ENST00000340736 / NM_001008701.3; = p.S325C on NM_014921.5) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61566013; called by muse, mutect2, varscan2
- ANGPT1 | c.1051C>G p.P351A | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.608); catalogued as COSV52450814; called by muse, mutect2, varscan2
- ASIC5 | c.913C>A p.Q305K | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1412479269, COSV73332889; called by muse, mutect2, varscan2
- BMP15 | c.1138G>C p.E380Q | Missense Mutation (SNP) | VAF 47/91 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53141385; called by muse, mutect2, varscan2
- CDH2 | c.752T>C p.I251T | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52291072; called by muse, mutect2, varscan2
- CDK5R2 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.738); catalogued as rs1258175546, COSV100225822; called by muse, mutect2
- CGNL1 | c.1006C>G p.P336A | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV55572722; called by muse, mutect2, varscan2
- CKS2 | c.132G>C p.R44S | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV58686739; called by muse, mutect2, varscan2
- CNTNAP1 | c.2635C>T p.R879W | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.138); catalogued as rs374737961; called by muse, mutect2, varscan2
- CRTC1 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100118918; called by muse, mutect2
- FAM3B | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV63613630; called by muse, mutect2, varscan2
- FMN2 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV100141835, COSV60418128; called by muse, mutect2, varscan2
- FN1 | c.2488C>T p.R830C | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV60550526; called by muse, mutect2, varscan2
- GALNT15 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV60218718; called by muse, mutect2
- GAS2L3 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); catalogued as COSV57158485; called by muse, mutect2, varscan2
- GPX1 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs771135780, COSV101346252; called by muse, varscan2
- GUCA1C | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53755106; called by muse, mutect2, varscan2
- HSPA14 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.575); catalogued as rs1439989042, COSV65684251, COSV65684495; called by muse, mutect2, varscan2
- IFT172 | c.1828C>T p.R610W | Missense Mutation (SNP) | VAF 144/488 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376749789; called by muse, mutect2, varscan2
- KCNJ16 | c.821A>T p.D274V | Missense Mutation (SNP) | VAF 27/164 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV52256109; called by muse, mutect2, varscan2
- KNOP1 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV54929255; called by muse, mutect2, varscan2
- MAP1B | c.4268G>C p.R1423T | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV57103682; called by muse, mutect2, varscan2
- MEGF11 | c.1130G>C p.G377A | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV56557639; called by muse, mutect2, varscan2
- MIS18BP1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as rs1310050845, COSV60372465; called by muse, mutect2
- MKRN3 | c.770G>C p.S257T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as COSV58811128, COSV58811410; called by muse, mutect2, varscan2
- MMP2 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54603966; called by muse, mutect2, varscan2
- MUC5B | c.13295C>T p.A4432V | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs369004960; called by muse, mutect2, varscan2
- MYH14 | c.3067G>C p.D1023H | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99221330; called by muse, mutect2, varscan2
- NCOA3 | c.691C>G p.Q231E | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.17); catalogued as COSV59071682, COSV59073327; called by muse, mutect2, varscan2
- NEB | c.5330T>C p.I1777T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.476); catalogued as rs1442538418, COSV51443310; called by muse, mutect2, varscan2
- NKX3-2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as rs751884954, COSV101219799; called by muse, varscan2
- NRP1 | c.1140C>G p.L380= | Splice Region (SNP) | VAF 30/110 reads (27%) | catalogued as COSV55173831; called by muse, mutect2
- OR2M5 | c.128C>A p.S43Y | Missense Mutation (SNP) | VAF 36/237 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.418); catalogued as COSV63546776; called by muse, mutect2, varscan2
- OR4N2 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as rs368630542, COSV60050638; called by muse, mutect2, varscan2
- PCDHA3 | c.274C>G p.R92G | Missense Mutation (SNP) | VAF 63/123 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65367909, COSV65369850; called by muse, mutect2, varscan2
- PEG3 | c.3078del p.E1027Sfs*118 | Frame Shift Del (DEL) | VAF 20/39 reads (51%) | catalogued as COSV55639636; called by mutect2, pindel, varscan2
- PKD1L1 | c.5045A>C p.Y1682S | Missense Mutation (SNP) | VAF 54/84 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56973587; called by muse, mutect2, varscan2
- PPEF2 | c.1822C>G p.R608G | Missense Mutation (SNP) | VAF 70/134 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); catalogued as rs774989139, COSV54420643, COSV54425047; called by muse, mutect2, varscan2
- PRKCI | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55521444; called by muse, mutect2, varscan2
- PRKCI | c.1023G>T p.M341I | Missense Mutation (SNP) | VAF 105/278 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55521455; called by muse, mutect2, varscan2
- PROCA1 | c.520G>A p.E174K (on ENST00000439862 / NM_001366301.1; = p.E146K on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs1025855176, COSV56388055; called by muse, mutect2, varscan2
- RABGEF1 | c.1190A>G p.Y397C (on ENST00000439720 / NM_001287061.2; = p.Y384C on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as rs771152566, COSV53164045; called by muse, mutect2, varscan2
- RHCE | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV53802509; called by muse, mutect2, varscan2
- RIF1 | c.6463C>T p.L2155F | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1359150380, COSV54621601; called by muse, mutect2, varscan2
- RIPOR3 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs762712601, COSV50397213; called by muse, mutect2, varscan2
- RO60 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.132); catalogued as rs745311922, COSV66474544; called by muse, mutect2, varscan2
- RUNX1T1 | c.841G>A p.G281S (on ENST00000265814 / NM_001198628.1; = p.G254S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.044); catalogued as rs763863514, COSV56141361; called by muse, mutect2, varscan2
- SERPINB5 | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV66975914; called by muse, mutect2
- SLC35F3 | c.259G>A p.A87T (on ENST00000366617 / NM_001300845.1; = p.A156T on NM_173508.4) | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV64020985; called by muse, mutect2, varscan2
- SLC9A4 | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as rs768703415, COSV99762579; called by muse, mutect2, varscan2
- SMARCA4 | c.2732G>A p.G911D | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867713307, COSV60804408; called by muse, mutect2, varscan2
- TAS2R20 | c.378G>C p.K126N | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.034); catalogued as rs1421311345, COSV67854698, COSV67860883; called by muse, mutect2, varscan2
- TBX5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV59863829; called by muse, mutect2, varscan2
- TDRD5 | c.689C>A p.T230K | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as COSV54248000; called by muse, mutect2
- TDRD7 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as COSV62430595; called by muse, mutect2, varscan2
- TMF1 | c.1584C>G p.I528M | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs755671358, COSV101275382; called by muse, mutect2
- TRAF3IP2 | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 31/57 reads (54%) | catalogued as COSV100389559; called by muse, mutect2, varscan2
- TRPM3 | c.2770G>A p.E924K (on ENST00000357533 / NM_001366142.2; = p.E767K on NM_020952.6) | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100676304; called by muse, mutect2
- ZMYM1 | c.2399G>A p.C800Y | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63252911; called by muse, mutect2, varscan2
- ZNF236 | c.1961A>G p.D654G | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV53494327; called by muse, mutect2, varscan2
- ZNF337 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 23/113 reads (20%) | catalogued as rs748292472, COSV53320529; called by muse, mutect2, varscan2
- ACOX2 | c.1038del p.K346Nfs*31 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- CFAP91 | c.1391del p.P464Lfs*21 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | called by mutect2, pindel, varscan2
- CR1 | c.2785del p.V929Ffs*26 | Frame Shift Del (DEL) | VAF 26/163 reads (16%) | called by mutect2, pindel, varscan2
- PLD5 | c.912del p.K305Nfs*22 (on ENST00000442594; = p.K243Nfs*22 on NM_001195811.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/86 reads (30%) | called by mutect2, pindel, varscan2
- RBMS3 | c.872del p.P291Lfs*26 | Frame Shift Del (DEL) | VAF 27/81 reads (33%) | called by mutect2, pindel, varscan2
- AMER2 | c.1527G>A p.P509= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV63437429; called by muse, mutect2
- ATXN2L | c.3012G>T p.A1004= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs763218468, COSV57376520; called by muse, mutect2, varscan2
- CACNA1S | c.1563C>G p.P521= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV100754497; called by mutect2, varscan2
- CEP250 | c.3204C>A p.L1068= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV61172715; called by muse, mutect2, varscan2
- CST11 | c.339C>T p.V113= (on ENST00000377009 / NM_130794.2; = p.V78= on NM_080830.3) | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV65441052; called by muse, mutect2, varscan2
- EFNA1 | c.492G>A p.K164= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV57597653; called by muse, mutect2, varscan2
- ESRRB | c.210C>T p.T70= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV55059761, COSV55065261; called by muse, mutect2, varscan2
- GRM5 | c.2235A>T p.G745= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs746490135, COSV59619727; called by muse, mutect2, varscan2
- KDM2B | c.2781G>A p.P927= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs370303545; called by muse, mutect2
- KLHL25 | c.774A>G p.A258= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV61995980; called by muse, mutect2, varscan2
- NAT16 | c.435G>A p.Q145= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV55865378; called by muse, mutect2, varscan2
- OLFML2A | c.736A>C p.R246= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV56584815; called by muse, mutect2
- PCDHAC2 | c.753C>T p.N251= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as rs147791062; called by muse, mutect2, varscan2
- PDPR | c.1389C>T p.Y463= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs752482405, COSV99847555; called by muse, mutect2, varscan2
- PTPRU | c.2547C>T p.L849= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV60533878; called by muse, mutect2
- RGL4 | c.201C>T p.F67= | Silent (SNP) | VAF 104/258 reads (40%) | catalogued as rs140951699, COSV51944706; called by muse, mutect2, varscan2
- RIPOR2 | c.558C>T p.Y186= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV52426713; called by muse, mutect2, varscan2
- SALL3 | c.1974G>A p.T658= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs759576604, COSV73306329; called by muse, mutect2, varscan2
- SEMG2 | c.1569A>G p.A523= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV65647778; called by muse, mutect2, varscan2
- SLCO5A1 | c.912C>A p.I304= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV52662781, COSV52664941; called by muse, varscan2
- SNRPD3 | c.96C>T p.L32= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as rs1420586014, COSV53183707; called by muse, mutect2, varscan2
- TEX101 | c.9G>C p.A3= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs757200433, COSV53662480, COSV99494647; called by muse, mutect2, varscan2
- TGFBR2 | c.1476G>A p.L492= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as rs1006428695, COSV55453121, COSV55456184, COSV55460299; called by muse, mutect2, varscan2
- TMEM62 | c.1344C>G p.L448= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV53042361; called by muse, mutect2, varscan2
- TTC21A | c.465G>C p.L155= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV57188132; called by muse, mutect2, varscan2
- TTN | c.58857T>C p.N19619= (on ENST00000591111; = p.N12195= on NM_003319.4) | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs1238332140, COSV60135143, COSV60241385; called by muse, mutect2, varscan2
- TUT7 | c.1644A>C p.S548= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV52897740; called by muse, mutect2, varscan2
- ZDHHC16 | c.537G>A p.L179= | Silent (SNP) | VAF 44/123 reads (36%) | catalogued as COSV61749489; called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.288C>T | RNA (SNP) | VAF 30/115 reads (26%) | called by muse, mutect2, varscan2
- RNF217-AS1 | n.1363C>G | RNA (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2
- TTN | c.10360+1127C>T | Intron (SNP) | VAF 88/234 reads (38%) | catalogued as rs1165172286, COSV60241410; called by muse, mutect2, varscan2
